Somatic mutation profile of tumor specimen MP2PRT-PASIEI-TMP1-A (aliquot MP2PRT-PASIEI-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASIEI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.3 years (4,868 days).
Specimen MP2PRT-PASIEI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d041232-d0fb-48af-8157-8a67666e1d0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASIEI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASIEI-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e60e5be-01cb-40dd-b5b1-9cb564847974

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 9, Silent 6, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 59/294 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CA1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767885397, COSV56278600, COSV56279407; called by muse, mutect2, varscan2
- CFAP206 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as rs1233881510; called by muse, mutect2, varscan2
- EGF | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1404201541, COSV54484576; called by muse, mutect2, varscan2
- PNMA3 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 55/387 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs782532724, COSV64721874, COSV64722415; called by muse, mutect2, varscan2
- TP53 | c.847_848insAGGGG p.R283Qfs*64 | Frame Shift Ins (INS) | VAF 54/260 reads (21%) | catalogued as COSV53297573, COSV99037230; called by pindel, varscan2
- GPR75 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- H2AC11 | c.309dup p.A104Rfs*19 | Frame Shift Ins (INS) | VAF 41/232 reads (18%) | called by mutect2, pindel, varscan2
- IGHV1-69 | chr14:106714681 GTCTCT>ACCCTC | Missense Mutation (ONP) | VAF 3/37 reads (8%) | called by mutect2*, pindel
- KMT2D | c.13487_13488dup p.G4497Lfs*23 | Frame Shift Ins (INS) | VAF 75/272 reads (28%) | called by mutect2, pindel, varscan2
- MMP15 | c.434C>A p.T145N | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RFX5 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ASB11 | c.708G>A p.A236= | Silent (SNP) | VAF 85/330 reads (26%) | catalogued as rs137906487; called by muse, mutect2, varscan2
- MCEMP1 | c.177G>A p.T59= | Silent (SNP) | VAF 79/176 reads (45%) | catalogued as rs142098368, COSV58040011, COSV58040669; called by muse, mutect2, varscan2
- P4HTM | c.405C>T p.I135= | Silent (SNP) | VAF 51/257 reads (20%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1173G>A p.P391= | Silent (SNP) | VAF 82/300 reads (27%) | catalogued as rs782063932, COSV56478446; called by muse, mutect2, varscan2
- SLC49A4 | c.984C>T p.G328= | Silent (SNP) | VAF 40/209 reads (19%) | catalogued as rs1360845332; called by muse, mutect2, varscan2
- THSD7B | c.3012C>T p.S1004= | Silent (SNP) | VAF 57/311 reads (18%) | catalogued as rs549789351, COSV55660062; called by muse, mutect2, varscan2
